TARGET case TARGET-30-PANGTS — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/ad358777-2a2e-56e8-b4e4-af1bc2db4d6b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.5 years (1,639 days); Year of diagnosis: 2004; Days to last follow up: 3,929 days (10.8 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PANGTS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
